TCGA case TCGA-29-1698 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18d21132-a795-4551-83ba-66483de423a2

Demographics
Sex at birth: female; Race: black or african american; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.7 years (19,611 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 2,078 days (5.7 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 237 days; Number of cycles: 9; Treatment dose: 5,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 237 days; Number of cycles: 9; Treatment dose: 2,603 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 328 days; Days to treatment end: 1,419 days (3.9 years); Treatment dose: 20 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 741 days (2.0 years); Days to treatment end: 909 days (2.5 years); Number of cycles: 5; Treatment dose: 570 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 741 days (2.0 years); Days to treatment end: 853 days (2.3 years); Number of cycles: 7; Treatment dose: 53 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,321 days (3.6 years); Days to treatment end: 1,349 days (3.7 years); Number of cycles: 2; Treatment dose: 510 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,321 days (3.6 years); Days to treatment end: 1,566 days (4.3 years); Number of cycles: 6; Treatment dose: 1,020 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,524 days (4.2 years); Days to treatment end: 1,580 days (4.3 years); Treatment dose: 600 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,580 days (4.3 years); Days to treatment end: 1,587 days (4.3 years); Number of cycles: 1; Treatment dose: 5 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,615 days (4.4 years); Days to treatment end: 1,783 days (4.9 years); Number of cycles: 7; Treatment dose: 68 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,811 days (5.0 years); Days to treatment end: 1,972 days (5.4 years); Number of cycles: 17; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,986 days (5.4 years); Days to treatment end: 2,028 days (5.6 years); Number of cycles: 3; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,051 days (5.6 years); Days to treatment end: 2,245 days (6.1 years); Number of cycles: 8; Treatment dose: 5 AUC; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 54.2 years (19,792 days); Days to diagnosis: 181 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 181 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 181 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 181 days; Evidence of recurrence type: Physical Examination.
- Days to follow up: 2,078 days (5.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Physical Examination; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-29-1698-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 45.
  Slide TCGA-29-1698-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 45.
- Sample TCGA-29-1698-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Gemcitabine HCL.
- Drug treatment 9: Pharmaceutical therapy drug name: Avastin (Bevacizumab).
- Drug treatment 11: Pharmaceutical therapy drug name: Toptecan; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,078 days; disease-specific survival: no event (censored), 2,078 days; disease-free interval: event (new tumor event after initially disease-free), 181 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 181 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1698-01A-01D-0559-01): tumor purity 0.6, ploidy 5.89, whole-genome doublings 2.
